Somatic mutation profile of tumor specimen TCGA-FA-A7DS-01A (aliquot TCGA-FA-A7DS-01A-11D-A382-10) from TCGA case TCGA-FA-A7DS, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 55.0 years (20,087 days).
Specimen TCGA-FA-A7DS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1409e930-2973-4188-b3e6-2adddabe38eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-A7DS-10A (Blood Derived Normal), aliquot TCGA-FA-A7DS-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deba68fc-8f8e-4e2c-9ca2-518ab9c29b10

The open-access MAF lists 114 somatic variants for this specimen: 79 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 34, Nonsense Mutation 6, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.33+1G>A p.X11_splice | Splice Site (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); catalogued as COSV67147966, COSV67148243; called by muse, mutect2, varscan2
- AAGAB | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.515); catalogued as COSV99972152; called by muse, mutect2
- ABCA13 | c.7727T>A p.L2576* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as rs544493291, COSV71283511; called by mutect2, varscan2
- AGAP6 | c.1501T>C p.W501R (on ENST00000374056 / NM_001365867.1; = p.W524R on NM_001077665.2) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100929181; called by muse, mutect2, varscan2
- ALLC | c.831T>G p.I277M | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.301); catalogued as rs1201536199, COSV52997006, COSV99378374; called by muse, mutect2, varscan2
- ASXL3 | c.5177C>A p.A1726D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99327034; called by muse, mutect2, varscan2
- BFAR | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99902510; called by muse, mutect2, varscan2
- C7orf61 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs764569240, COSV100190405; called by muse, mutect2, varscan2
- CACNG7 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55813141; called by muse, mutect2, varscan2
- CDH8 | c.1797C>A p.C599* | Nonsense Mutation (SNP) | VAF 42/110 reads (38%) | catalogued as COSV100184578; called by muse, mutect2, varscan2
- COL4A1 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV101011640; called by muse, mutect2
- CPXM1 | c.612C>A p.Y204* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV66046242, COSV66046361; called by muse, mutect2
- DAPK1 | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV100802902, COSV63793066; called by muse, mutect2, varscan2
- DHX38 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV51701394, COSV99194681; called by muse, mutect2, varscan2
- DLGAP3 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs766044952, COSV99333304; called by muse, varscan2
- DQX1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV101098991; called by muse, mutect2
- ELAVL1 | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100688478; called by muse, mutect2, varscan2
- ELAVL2 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 60/222 reads (27%) | catalogued as COSV99807475; called by muse, mutect2, varscan2
- ERBB4 | c.1880G>C p.G627A | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV53499337, COSV53540285, COSV99635640; called by muse, mutect2, varscan2
- ETV6 | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV67150696; called by muse, mutect2, varscan2
- FAM124A | c.1364C>A p.A455E (on ENST00000322475 / NM_001242312.2; = p.A491E on NM_145019.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99696503; called by muse, mutect2, varscan2
- FAM155A | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV101030877, COSV65592289; called by muse, mutect2, varscan2
- FAT4 | c.8135G>A p.G2712D | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs893036381, COSV58696719; called by muse, mutect2, varscan2
- GUCY1B1 | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs1222758981, COSV100026012; called by muse, mutect2
- H4C8 | c.197T>A p.V66E | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV99175525; called by muse, mutect2, varscan2
- HLA-C | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as rs281860470, COSV100881165, COSV66111225; called by muse, varscan2
- IGHG1 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 74/128 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs751791072; called by muse, varscan2
- IGHG2 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1474281959; called by muse, mutect2, varscan2
- IGHM | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs782275420; called by muse, mutect2, varscan2
- IGHV4-34 | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs11267027; called by muse, mutect2, varscan2
- IGLV2-14 | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as rs774559022; called by muse, varscan2
- IGLV2-14 | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs776014249; called by muse, varscan2
- IGLV2-23 | c.149G>C p.S50T | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs372411137; called by muse, mutect2, varscan2
- ITGA6 | c.3295C>T p.R1099W (on ENST00000442250; = p.R1060W on NM_001079818.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs370676535; called by muse, mutect2, varscan2
- KRIT1 | c.1226A>C p.K409T | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100388987; called by muse, mutect2, varscan2
- KRT6A | c.39C>A p.S13R | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100417310; called by muse, mutect2, varscan2
- MUC16 | c.43333A>C p.T14445P | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV101110125; called by muse, mutect2, varscan2
- NEB | c.11632C>T p.R3878C | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs762876022, COSV50806160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEURL1 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs769464925, COSV63914435; called by muse, mutect2, varscan2
- NKD2 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs376557535, COSV56891949, COSV99724516; called by muse, mutect2, varscan2
- NOP2 | c.625G>A p.G209S (on ENST00000322166 / NM_001258308.2; = p.G205S on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100445305; called by muse, mutect2, varscan2
- PAQR7 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs769434667, COSV65352223; called by muse, mutect2, varscan2
- PCLO | c.6856G>T p.A2286S | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV100439227; called by muse, mutect2, varscan2
- PDE3A | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs532703635, COSV100762954; called by muse, mutect2, varscan2
- PDE3A | c.1939A>T p.R647* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100762956; called by muse, mutect2, varscan2
- PIM1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV100998571, COSV104423821, COSV65164906; called by muse, varscan2
- PIM1 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV100998805; called by muse, varscan2
- PIM1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV65164639, COSV65166716; called by muse, varscan2
- PIM1 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV100998809; called by muse, mutect2, varscan2
- PPEF1 | c.1267T>C p.S423P | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100584128; called by muse, mutect2, varscan2
- PPP1R36 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); catalogued as rs767011282, COSV53901808, COSV53904085; called by muse, mutect2, varscan2
- PTPRZ1 | c.6022T>C p.Y2008H | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101100934; called by muse, mutect2, varscan2
- RXFP1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100314323; called by muse, mutect2, varscan2
- SECISBP2L | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs1380861580, COSV99961125; called by muse, mutect2, varscan2
- SERPINH1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); catalogued as rs766813083, COSV63997972; called by muse, mutect2, varscan2
- SLC44A2 | c.140A>C p.Y47S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100213522; called by muse, mutect2, varscan2
- SYNDIG1L | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV100526615; called by muse, mutect2, varscan2
- SYNE1 | c.3867G>T p.K1289N (on ENST00000367255 / NM_182961.4; = p.K1296N on NM_033071.3) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99583566; called by muse, mutect2, varscan2
- TENM4 | c.2012G>T p.G671V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1370618984, COSV99580571; called by muse, mutect2, varscan2
- TNFAIP2 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV100281143; called by muse, mutect2, varscan2
- TRIM29 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100532086; called by muse, mutect2, varscan2
- YTHDF2 | c.1502T>C p.F501S | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100863880; called by muse, mutect2, varscan2
- ZFPM2 | c.2753A>C p.K918T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV101023696, COSV65872517; called by muse, mutect2, varscan2
- ZIC3 | c.786C>G p.S262R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54976552, COSV99799641; called by muse, mutect2, varscan2
- ZNF630 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99332648; called by muse, mutect2, varscan2
- DMD | c.4472dup p.S1492Efs*19 | Frame Shift Ins (INS) | VAF 65/208 reads (31%) | called by mutect2, pindel, varscan2
- HLA-B | c.891dup p.W298Mfs*36 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | called by mutect2, pindel, varscan2
- IGHG1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- IGHG1 | c.537C>G p.Y179* | Nonsense Mutation (SNP) | VAF 28/45 reads (62%) | called by muse, varscan2
- IGHG1 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, varscan2
- IGHG1 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, varscan2
- IGHG2 | c.530G>C p.S177T | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHG2 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- IGHG4 | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHG4 | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHM | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- KMT2D | c.12100_12103del p.S4034Qfs*15 | Frame Shift Del (DEL) | VAF 41/66 reads (62%) | called by mutect2, pindel, varscan2
- MRPL14 | c.434_437del p.V145Efs*12 | Frame Shift Del (DEL) | VAF 27/57 reads (47%) | called by mutect2, pindel, varscan2
- UBASH3A | c.124_135del p.L42_T45del | In Frame Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- ALDH1B1 | c.1344G>A p.V448= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100891012; called by muse, mutect2, varscan2
- ANKFN1 | c.180C>T p.A60= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs1412886555, COSV100594343; called by muse, mutect2, varscan2
- BAHCC1 | c.5187G>A p.S1729= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs555426689, COSV100312144; called by muse, varscan2
- BCOR | c.1356T>C p.A452= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100654354; called by muse, mutect2, varscan2
- EGR1 | c.103C>T p.L35= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs558452520, COSV53520131; called by muse, varscan2
- EMC6 | c.183G>A p.L61= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs769603435, COSV99835813; called by muse, mutect2, varscan2
- FCRL5 | c.81C>T p.L27= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV100709427; called by muse, mutect2, varscan2
- FGF3 | c.510C>T p.R170= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV61926702; called by muse, mutect2
- FRMPD3 | c.4806C>T p.T1602= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99347323; called by muse, mutect2, varscan2
- GABRP | c.321G>T p.L107= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV54661869, COSV99517180; called by muse, mutect2, varscan2
- GPR50 | c.615T>A p.G205= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99506833; called by muse, mutect2, varscan2
- H1-4 | c.366G>A p.K122= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs200272831, COSV99175419; called by muse, mutect2, varscan2
- HCN4 | c.1962C>T p.D654= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs754108543, COSV56082688; called by muse, mutect2, varscan2
- HLA-C | c.303C>T p.S101= | Silent (SNP) | VAF 46/68 reads (68%) | catalogued as rs281860412, COSV100881167; called by muse, mutect2, varscan2
- IGHG3 | c.327C>T p.H109= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs762251028; called by muse, mutect2, varscan2
- IGHG4 | c.537G>A p.T179= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs765941412; called by muse, varscan2
- IGHG4 | c.246C>T p.T82= | Silent (SNP) | VAF 21/63 reads (33%) | called by muse, varscan2
- IGHM | c.288C>T p.N96= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- IGLC2 | c.195G>A p.K65= | Silent (SNP) | VAF 62/224 reads (28%) | catalogued as rs1803804; called by muse, varscan2
- IGLV3-16 | c.190C>T p.L64= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as rs553194207; called by muse, varscan2
- ITIH5 | c.612G>A p.P204= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs1425543668, COSV99904196; called by muse, mutect2, varscan2
- KRT3 | c.1299G>A p.E433= | Silent (SNP) | VAF 94/169 reads (56%) | catalogued as rs369576134; called by muse, mutect2, varscan2
- LCN8 | c.213T>G p.V71= (on ENST00000612714 / NM_001345934.1; = p.V48= on NM_178469.3) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100293678; called by muse, mutect2, varscan2
- NXF3 | c.411C>T p.C137= | Silent (SNP) | VAF 71/210 reads (34%) | catalogued as COSV101222116; called by muse, mutect2, varscan2
- OR4K5 | c.111C>A p.V37= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as COSV60003429; called by muse, mutect2, varscan2
- PIM1 | c.21C>T p.N7= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs756412850, COSV100998728, COSV65166667; called by muse, mutect2, varscan2
- PIM1 | c.198C>T p.I66= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs1033497376, COSV100998803; called by muse, mutect2, varscan2
- PIM1 | c.291C>T p.S97= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV65165165, COSV65165406; called by muse, varscan2
- SNX8 | c.708C>T p.R236= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs778518638, COSV56127011, COSV56127447, COSV99771232; called by muse, mutect2, varscan2
- TACC2 | c.1047C>T p.G349= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV57756463; called by muse, mutect2, varscan2
- TNS4 | c.528C>T p.F176= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs758045618, COSV54183351; called by muse, mutect2
- VWF | c.7806C>A p.T2602= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV99780544; called by muse, mutect2, varscan2
- ZFP37 | c.126C>T p.S42= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100953371; called by muse, mutect2, varscan2
- ZNF112 | c.1494A>T p.P498= (on ENST00000337401 / NM_001083335.2; = p.P492= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV100496414; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901036 C>T | 3'Flank (SNP) | VAF 68/378 reads (18%) | called by muse, varscan2
